Somatic mutation profile of tumor specimen MMRF_1502_1_BM_CD138pos (aliquot MMRF_1502_1_BM_CD138pos_T2_KAS5U_L02369) from MMRF case MMRF_1502, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.5 years (21,383 days).
Specimen MMRF_1502_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cfa27ab-b77b-4d39-85fa-c36b010d54cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1502_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1502_1_PB_CD3pos_C3_KAS5U_L02377; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e464272-b77c-4a61-b966-f917c9b63c0d

The open-access MAF lists 107 somatic variants for this specimen: 48 protein-altering or splice-affecting, 10 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 20, Intron 16, Silent 10, 5'UTR 9, 5'Flank 3, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 2, Splice Region 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 85/315 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD50 | c.2588G>T p.C863F | Missense Mutation (SNP) | VAF 46/365 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101538954; called by muse, mutect2, varscan2
- BPI | c.158C>T p.T53M (on ENST00000262865; = p.T49M on NM_001725.3) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as rs769218495, COSV53404954; called by muse, varscan2
- CCDC59 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs752381737; called by muse, mutect2, varscan2
- CFAP46 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1439877538; called by muse, mutect2, varscan2
- CNTNAP2 | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs747922335, COSV62158230, COSV99080851; called by muse, mutect2, varscan2
- CR2 | c.2915C>T p.S972L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as rs772806588; called by muse, mutect2, varscan2
- CSPG4 | c.3874C>T p.R1292C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs531406813; called by muse, varscan2
- ELAVL1 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs763270784, COSV60965768; called by muse, mutect2, varscan2
- GDPD4 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV60020855; called by muse, varscan2
- IGHV4-34 | c.172T>C p.Y58H | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs587643115; called by muse, varscan2
- KIFC2 | c.29A>C p.Y10S | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV100023385; called by muse, mutect2, varscan2
- MAGI1 | c.4237C>T p.R1413W | Missense Mutation (SNP) | VAF 100/306 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); catalogued as rs1213252244, COSV100440966; called by muse, mutect2, varscan2
- NACC2 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs1375368858, COSV53201241; called by muse, mutect2, varscan2
- NYX | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as rs763723615, COSV100699453; called by muse, mutect2, varscan2
- OLFML2B | c.949+1G>A p.X317_splice | Splice Site (SNP) | VAF 28/69 reads (41%) | catalogued as rs748357924, COSV54194970, COSV99668018; called by muse, mutect2, varscan2
- PROKR2 | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 85/155 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.146); catalogued as rs778739474; called by muse, mutect2, varscan2
- SGK1 | c.77-6C>T | Splice Region (SNP) | VAF 60/166 reads (36%) | catalogued as COSV52804774; called by muse, varscan2
- SPTA1 | c.1052G>T p.S351I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as rs929975694; called by muse, mutect2, varscan2
- TOR1AIP1 | c.329A>G p.Q110R | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.022); catalogued as rs1021447566; called by muse, mutect2
- VPS13B | c.9851T>A p.I3284N | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV62142326; called by mutect2, varscan2
- AKAP17A | c.1666C>A p.Q556K | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- AKAP6 | c.136A>G p.M46V | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP2B1 | c.689_709del p.N230_A237delinsT | In Frame Del (DEL) | VAF 34/91 reads (37%) | called by mutect2, pindel, varscan2
- CATSPERG | c.1504A>C p.K502Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH8 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CORIN | c.575G>C p.C192S | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENPP1 | c.1514A>C p.D505A | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- FSIP2 | c.6614C>T p.S2205L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GALNTL6 | c.860del p.M287Sfs*48 | Frame Shift Del (DEL) | VAF 25/87 reads (29%) | called by mutect2, pindel, varscan2
- H2BC12 | c.137_150del p.L46Pfs*8 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | called by mutect2, pindel, varscan2
- H2BC8 | c.363G>C p.K121N | Missense Mutation (SNP) | VAF 69/127 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- IGHV2-70D | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, varscan2
- IGLV3-22 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 37/38 reads (97%) | SIFT tolerated (0.1); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- KCNU1 | c.353T>C p.I118T | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, varscan2
- LRRCC1 | c.654G>T p.Q218H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- MDP1 | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NIPBL | c.5010+2T>C p.X1670_splice | Splice Site (SNP) | VAF 38/87 reads (44%) | called by muse, mutect2, varscan2
- OTOP2 | c.72G>A p.W24* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- PCDH18 | c.3133A>C p.K1045Q | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- PHF14 | c.2561G>C p.R854T | Missense Mutation (SNP) | VAF 80/127 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PQBP1 | c.650G>A p.W217* | Nonsense Mutation (SNP) | VAF 84/88 reads (95%) | called by muse, varscan2
- PSMC5 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.2035G>A p.V679M | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SPIB | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SUSD4 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM67 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 90/192 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- URB1 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2
- COL20A1 | c.2880G>A p.Q960= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs764534590; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1044C>A p.T348= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as COSV62571021; called by muse, mutect2, varscan2
- EPB41L3 | c.2088C>T p.D696= | Silent (SNP) | VAF 46/121 reads (38%) | called by muse, varscan2
- IGHV1-69 | c.66G>A p.Q22= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs372831324; called by mutect2, varscan2
- IGLV3-25 | c.66G>A p.E22= | Silent (SNP) | VAF 38/38 reads (100%) | catalogued as rs376421895; called by muse, mutect2, varscan2
- MPDZ | c.1278C>T p.D426= | Silent (SNP) | VAF 69/71 reads (97%) | catalogued as rs1242887149; called by muse, mutect2, varscan2
- PLXND1 | c.204G>A p.A68= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- TUB | c.366C>T p.A122= (on ENST00000299506 / NM_177972.3; = p.A177= on NM_003320.4) | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as rs546088028; called by muse, mutect2
- UNC80 | c.3855C>T p.G1285= | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as rs917171654; called by muse, mutect2, varscan2
- ZBTB7C | c.669G>A p.R223= | Silent (SNP) | VAF 41/123 reads (33%) | called by muse, mutect2, varscan2
- ANKRD46 | c.636+1114A>C | Intron (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- B3GAT2 | c.*2473T>A | 3'UTR (SNP) | VAF 45/98 reads (46%) | called by muse, mutect2, varscan2
- BNIP3P1 | n.845A>T | RNA (SNP) | VAF 52/252 reads (21%) | called by muse, mutect2, varscan2
- C1orf216 | c.*326A>G | 3'UTR (SNP) | VAF 138/262 reads (53%) | called by muse, mutect2, varscan2
- CCDC184 | c.*1112C>T | 3'UTR (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- CEP126 | c.-143C>G | 5'UTR (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- CHPF2 | c.-1406C>T | 5'UTR (SNP) | VAF 13/39 reads (33%) | catalogued as rs942122041; called by muse, mutect2, varscan2
- CLMN | c.*174del | 3'UTR (DEL) | VAF 21/56 reads (38%) | catalogued as rs1310536172; called by mutect2, varscan2
- DNAH12 | c.1335+3227A>G | Intron (SNP) | VAF 44/141 reads (31%) | called by muse, mutect2, varscan2
- EEF1A1 | c.*1121T>G | 3'UTR (SNP) | VAF 19/41 reads (46%) | catalogued as rs923827262; called by muse, mutect2, varscan2
- ERBB2 | c.2725+118G>A | Intron (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- FMN2 | c.*406A>T | 3'UTR (SNP) | VAF 73/125 reads (58%) | called by muse, mutect2, varscan2
- GLCCI1 | c.*478A>G | 3'UTR (SNP) | VAF 12/60 reads (20%) | called by mutect2, varscan2
- H3-3B | c.*49T>C | 3'UTR (SNP) | VAF 76/166 reads (46%) | catalogued as rs747751713; called by muse, mutect2, varscan2
- HHIPL1 | c.*4094G>A | 3'UTR (SNP) | VAF 22/41 reads (54%) | catalogued as rs974102431; called by muse, mutect2, varscan2
- IKZF3 | c.-120C>T | 5'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- ISCA2 | c.*1331G>T | 3'UTR (SNP) | VAF 39/63 reads (62%) | called by muse, mutect2, varscan2
- LGALS9C | chr17:18475822 C>T | 5'Flank (SNP) | VAF 25/26 reads (96%) | called by muse, mutect2, varscan2
- LLGL2 | c.*22G>A | 3'UTR (SNP) | VAF 62/137 reads (45%) | catalogued as rs758113032; called by muse, mutect2, varscan2
- LRGUK | c.*310T>C | 3'UTR (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- LTB | c.162+34G>A | Intron (SNP) | VAF 26/52 reads (50%) | catalogued as rs558646836, COSV53001046; called by muse, mutect2, varscan2
- LTBP4 | c.451+1344G>A | Intron (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- LY9 | c.455-139C>T | Intron (SNP) | VAF 11/13 reads (85%) | called by muse, mutect2, varscan2
- MEST | c.-26G>A | 5'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- MFSD11 | chr17:76735995 C>T | 5'Flank (SNP) | VAF 22/45 reads (49%) | catalogued as rs1194647876, COSV100333811; called by muse, mutect2, varscan2
- MTO1 | c.*6793A>C | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- NHSL2 | c.-361G>T | 5'UTR (SNP) | VAF 30/31 reads (97%) | called by muse, mutect2, varscan2
- NKAIN2 | c.474+21G>A | Intron (SNP) | VAF 89/171 reads (52%) | catalogued as rs367942867; called by muse, mutect2, varscan2
- OR2B11 | chr1:247452156 C>T | 5'Flank (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- PHF20L1 | c.2388-31del | Intron (DEL) | VAF 30/87 reads (34%) | called by pindel, varscan2
- PLEKHA5 | c.1845+3134C>T | Intron (SNP) | VAF 12/54 reads (22%) | catalogued as rs1207237711; called by muse, mutect2
- PPFIBP1 | c.-36+21223C>T | Intron (SNP) | VAF 136/379 reads (36%) | called by muse, mutect2, varscan2
- RNF220 | c.993+100A>C | Intron (SNP) | VAF 31/58 reads (53%) | catalogued as rs1319544358; called by muse, mutect2, varscan2
- SEL1L | c.*2825_*2827del | 3'UTR (DEL) | VAF 22/46 reads (48%) | catalogued as rs1395462029; called by pindel, varscan2
- SGK1 | c.76+55T>C | Intron (SNP) | VAF 123/237 reads (52%) | called by muse, varscan2
- SLC8B1 | c.1258-102A>T | Intron (SNP) | VAF 26/44 reads (59%) | called by mutect2, varscan2
- SRGAP1 | c.*2175T>A | 3'UTR (SNP) | VAF 6/22 reads (27%) | called by muse, varscan2
- ST6GALNAC4 | c.12+141T>A | Intron (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- ST8SIA2 | c.*3983C>T | 3'UTR (SNP) | VAF 99/397 reads (25%) | catalogued as rs1318845488, COSV51567163; called by muse, mutect2, varscan2
- STEAP2 | c.*84T>C | 3'UTR (SNP) | VAF 25/69 reads (36%) | catalogued as rs984135915; called by muse, mutect2, varscan2
- STON2 | c.2784+2228A>C | Intron (SNP) | VAF 196/395 reads (50%) | called by muse, mutect2, varscan2
- TAF12 | c.*345C>T | 3'UTR (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- TBC1D5 | c.*115G>A | 3'UTR (SNP) | VAF 36/50 reads (72%) | called by muse, mutect2
- THSD4 | c.*2855A>G | 3'UTR (SNP) | VAF 96/204 reads (47%) | catalogued as rs931893700; called by muse, mutect2, varscan2
- ZFP36L1 | c.-348T>C | 5'UTR (SNP) | VAF 20/41 reads (49%) | called by muse, varscan2
- ZFP36L1 | c.-706T>C | 5'UTR (SNP) | VAF 54/128 reads (42%) | called by muse, varscan2
- ZFP36L1 | c.-709A>G | 5'UTR (SNP) | VAF 50/121 reads (41%) | catalogued as rs1427643391; called by muse, varscan2
- ZFP36L1 | c.-710T>G | 5'UTR (SNP) | VAF 52/123 reads (42%) | called by muse, varscan2
- ZWINT | c.256+31G>A | Intron (SNP) | VAF 20/32 reads (63%) | catalogued as rs564370685; called by muse, mutect2, varscan2
